Gene-level copy-number profile of tumor specimen TCGA-XJ-A9DX-01A from TCGA case TCGA-XJ-A9DX, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-XJ-A9DX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.c6dc4750-6cb1-4fdf-83fa-c7f24801d653.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XJ-A9DX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 848 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9f3213ed-daff-4188-909c-a25f1b65466a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,619; copy number 2: 38,495; copy number 3: 13,040; copy number 4: 2,449; copy number 5: 770; copy number 6: 387; copy number 8: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XJ-A9DX-01A-11D-A376-01): tumor purity 0.74, ploidy 2.36, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,172 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:91,680,343–92,063,538, 4 genes, copy number 5 (within-gene range 4–5): TGFBR3, RN7SL653P, BRDT, EPHX4.
- chr1:151,131,685–152,196,699, 64 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:152,205,858–152,224,193, 2 genes, copy number 6: AL589986.2, HRNR.
- chr2:161,558,544–163,736,012, 21 genes, copy number 5: AC092654.1, AC062022.1, AC062022.2, KRT18P46, RPEP5, DPP4, DPP4-DT, TIMM8AP1, EIF3EP2, AC008063.1, GCG, AC007750.1, FAP, IFIH1, GCA, KCNH7, RNA5SP109, KCNH7-AS1, RPL7P61, RNU6-627P, FIGN.
- chr3:95,654,423–97,752,460, 14 genes, copy number 6: MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1, EPHA6, AC117470.1.
- chr4:6,320,578–7,112,399, 24 genes, copy number 5 (within-gene range 4–5): PPP2R2C, MAN2B2, MRFAP1, LINC02482, AC093323.4, AC093323.1, LINC02481, AC093323.2, S100P, AC093323.3, MRFAP1L1, BLOC1S4, AC106045.1, KIAA0232, TBC1D14, AC097382.3, AC097382.1, RN7SKP292, AC097382.2, CCDC96, TADA2B, GRPEL1, LINC02447, RN7SKP36.
- chr4:14,111,968–14,453,625, 6 genes, copy number 6 (within-gene range 4–6): LINC01085, AC073848.1, AC092546.1, AC006296.3, AC006296.2, AC006296.1.
- chr4:46,918,900–48,134,250, 20 genes, copy number 6 (within-gene range 3–6): GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, AC107398.5, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6.
- chr5:55,625,845–56,111,329, 12 genes, copy number 5 (within-gene range 3–5): SLC38A9, DDX4, AC016632.1, RNA5SP183, HNRNPH1P3, IL31RA, IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1.
- chr6:46,652,915–50,181,007, 55 genes, copy number 5–8 (within-gene range 3–8): SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1, FO393412.1, AL391538.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1.
- chr7:29,806,486–33,877,180, 78 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:40,964,667–42,264,100, 6 genes, copy number 6: LINC01450, LINC01449, INHBA, INHBA-AS1, GLI3, HMGN2P30.
- chr7:43,508,728–44,334,577, 34 genes, copy number 6: LUARIS, STK17A, COA1, BLVRA, AC005189.1, MRPS24, URGCP-MRPS24, URGCP, TUBG1P, UBE2D4, POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1, AC017116.2, POLR2J4, RASA4CP, LINC00957, DBNL, MIR6837, PGAM2, AC017116.1, POLM, MIR6838, AEBP1, MIR4649, POLD2, RNA5SP230, MYL7, GCK, YKT6, CAMK2B.
- chr7:100,200,653–100,968,347, 51 genes, copy number 5 (within-gene range 2–5): CASTOR3, SPDYE3, PMS2P1, Y_RNA, STAG3L5P, STAG3L5P-PVRIG2P-PILRB, PILRB, PVRIG2P, MIR6840, PILRA, AC005071.1, ZCWPW1, MEPCE, AC092849.1, PPP1R35, PPP1R35-AS1, C7orf61, TSC22D4, AC092849.2, NYAP1, AC069281.1, RN7SL416P, AGFG2, IRS3P, SAP25, AC069281.2, LRCH4, FBXO24, PCOLCE-AS1, PCOLCE, MOSPD3, TFR2, ACTL6B, GNB2, GIGYF1, POP7, EPO, ZAN, EPHB4, RN7SL750P, SLC12A9, SLC12A9-AS1, TRIP6, MIR6875, SRRT, UFSP1, ACHE, RN7SL549P, RPS29P15, MUC3A, AC254629.1.
- chr7:150,791,285–151,954,985, 42 genes, copy number 5: TMEM176B, TMEM176A, AOC1, KCNH2, NOS3, ATG9B, ABCB8, AC010973.1, ASIC3, CDK5, SLC4A2, AC010973.3, AC010973.2, FASTK, TMUB1, AGAP3, GBX1, ASB10, IQCA1L, H2BE1, ABCF2-H2BE1, ABCF2, CHPF2, MIR671, SMARCD3, AC021097.1, AC005486.1, NUB1, WDR86, WDR86-AS1, AC005996.1, CRYGN, MIR3907, RN7SL76P, RHEB, ETF1P2, PRKAG2, AC093583.1, PRKAG2-AS1, RNU6-604P, Y_RNA, AC074257.1.
- chr8:13,741,809–13,909,780, 3 genes, copy number 5: AC022880.1, AC022690.2, AC022690.1.
- chr8:123,288,355–126,292,788, 62 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr9:79,391,304–80,034,555, 10 genes, copy number 5: CHCHD2P9, LNCARSR, TLE4, AL161912.3, NPAP1P6, AL161912.1, AL161912.2, AL161912.4, AL161782.1, LINC01507.
- chr9:119,935,053–122,688,372, 53 genes, copy number 5: LINC01613, AL441989.1, MIR147A, CDK5RAP2, MEGF9, AHCYP2, FBXW2, B3GNT10, AL161911.1, PSMD5, CUTALP, PHF19, TRAF1, C5, CNTRL, RAB14, RN7SL181P, GSN, AL513122.1, AL513122.2, GSN-AS1, STOM, AL359644.1, GGTA1, RN7SL187P, HMGB1P37, DAB2IP, AL357936.1, AL596244.1, TTLL11, TTLL11-IT1, MIR4478, NDUFA8, MORN5, LHX6, RBM18, MRRF, PTGS1, AL162424.1, AL359636.1, AL359636.2, OR1J1, OR1J2, OR1J4, OR1N1, OR1N2, OR1L8, OR1H1P, OR1Q1, OR1B1, OR1L1, OR1L3, TLK1P1.
- chr10:5,684,838–9,287,057, 63 genes, copy number 5–6 (broad region; genes not listed).
- chr11:77,514,936–78,175,323, 25 genes, copy number 6 (within-gene range 3–6): CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1.
- chr11:94,874,052–95,146,004, 15 genes, copy number 6: AP002383.2, ST13P11, CWC15, KDM4D, AP002383.1, KDM4E, AP002383.5, AP002383.3, AP002383.4, KDM4F, AP001264.1, SRSF8, ENDOD1, BUD13P1, AP000787.2.
- chr11:120,936,102–122,619,274, 27 genes, copy number 5: HMGB1P42, TBCEL, TBCEL-TECTA, TECTA, AP001124.1, RPS4XP12, SC5D, BMPR1AP2, AP002365.1, AP000977.1, SORL1, AP001977.1, AP001924.1, RNU6-256P, AP001924.2, MIR100HG, MIR125B1, BLID, MIRLET7A2, MIR100, AP000755.1, AP000755.2, RNU4ATAC10P, RNU4ATAC5P, RNU6-592P, GLULP3, AP002469.1.
- chr11:122,679,801–122,726,311, 2 genes, copy number 5: AP002762.3, AP002762.1.
- chr11:127,188,885–127,941,654, 6 genes, copy number 5: AP003121.1, LINC02712, RN7SKP121, RN7SKP279, AP003532.1, DNAJB6P1.
- chr11:128,934,731–131,004,429, 40 genes, copy number 5–6: TP53AIP1, ARHGAP32, RNU6-876P, Y_RNA, RNU6-874P, ZNF123P, BARX2, RPS27P20, AP003500.1, LINC01395, AP003327.2, AP003327.1, TMEM45B, NFRKB, PRDM10, LINC00167, AP003041.1, ELOBP2, AP003041.2, APLP2, RPL34P21, U4, ST14, ZBTB44, NDUFAF2P2, DDX18P5, RN7SL778P, ZBTB44-DT, ADAMTS8, ADAMTS15, AP004371.1, BAK1P2, MIR8052, LINC02873, AP003486.2, PPP1R10P1, LINC02551, SNX19, AP003486.1, RN7SL167P.
- chr12:14,169,746–15,006,999, 28 genes, copy number 5: AC092470.1, AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1, RPL30P11, ATF7IP, PLBD1, AC008114.1, RN7SKP134, PLBD1-AS1, GUCY2C, AC010168.1, AC010168.2, H4-16, H2AJ, WBP11, C12orf60, SMCO3, AC007655.2, ART4, AC007655.1, MGP, ERP27, ARHGDIB, PDE6H, LINC01489.
- chr12:15,112,363–15,155,283, 2 genes, copy number 5: RERG-IT1, RERG-AS1.
- chr12:45,014,672–46,876,784, 32 genes, copy number 5: DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4.
- chr12:66,347,431–67,069,162, 1 gene, copy number 5 (within-gene range 3–5): GRIP1.
- chr12:66,950,754–70,354,993, 78 genes, copy number 5 (broad region; genes not listed).
- chr12:78,863,993–79,778,451, 9 genes, copy number 5 (within-gene range 3–5): SYT1, AC090709.1, AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2.
- chr12:79,818,784–79,825,496, 2 genes, copy number 5: AC073569.3, AC073569.1.
- chr13:25,863,250–26,905,861, 20 genes, copy number 5: AL157366.1, RN7SL741P, RNY1P3, SHISA2, LINC00415, ATP8A2P3, PRUNEP1, RNF6, AL138966.2, AL138966.1, THAP12P6, CDK8, AL159159.1, AL353789.1, WASF3, RPS3AP44, WASF3-AS1, AL159978.1, GPR12, FGFR1OP2P1.
- chr13:87,427,214–87,803,808, 6 genes, copy number 6 (within-gene range 3–6): MIR4500HG, AL355578.1, MIR4500, SLITRK5, AL445647.2, LINC00397.
- chr13:108,207,439–111,305,737, 55 genes, copy number 5–6: LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, AL138694.1, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1, NAXD, CARS2, ING1, RPL21P107, LINC00567, PRECSIT, ANKRD10, ANKRD10-IT1, AL442128.2, PARP1P1, AL442128.1, LINC00431, LINC00368, AL353704.2, ARHGEF7-AS2, ARHGEF7, ARHGEF7-IT1, ARHGEF7-AS1, AL353704.1, AL390754.1.
- chr14:45,079,849–46,501,903, 16 genes, copy number 6: AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871.
- chr15:23,685,400–25,581,122, 114 genes, copy number 5–6 (broad region; genes not listed).
- chr18:46,326,809–47,594,550, 30 genes, copy number 5 (within-gene range 1–5): RNF165, AC015959.1, AC018931.1, LOXHD1, ST8SIA5, AC090311.1, AC090241.2, AC090241.3, PIAS2, AC090241.1, AC090373.1, KATNAL2, ELOA3D, ELOA3C, ELOA3B, ELOA3, ELOA2, AC012254.5, AC012254.1, AC012254.3, HDHD2, AC012254.2, AC012254.4, IER3IP1, SKOR2, RNU6-1131P, AC051635.1, MIR4527HG, MIR4527, AC102797.2.
- chr19:36,259,540–37,210,512, 36 genes, copy number 5 (within-gene range 2–5): LINC00665, AC092296.2, ZFP14, AC092296.1, AC092296.4, ZFP82, AC092296.3, ZNF566, AC092295.2, CTBP2P7, ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2.

Autosomal genes at a single copy (total copy number 1): 2,684. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
